Surgical pathology report (de-identified scan), TCGA case TCGA-56-8626, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-8626-01A (Primary Tumor).

[page 1 of 5]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. - H.) LUNG, LEFT UPPER LOBE, AND MEDIASTINAL LYMPH NODES, LOBECTOMY WITH MEDIASTINAL LYMPH NODE BIOPSIES:

- INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.
- TUMOR SIZE: 1.9 CM IN DIAMETER.
- TUMOR PRESENT IN THE SEPARATELY SUBMITTED LEFT UPPER LOBE WEDGE RESECTION (SPECIMEN A).
- SQUAMOUS CELL CARCINOMA IN SITU, PRESENT IN BRONCHI IN THE VICINITY OF THE INVASIVE CARCINOMA.
- THE BRONCHIAL RESECTION MARGIN IS FREE OF TUMOR.
- FOCAL EMPHYSEMATOUS CHANGE IN LUNG TISSUE AWAY FROM TUMOR.
- NINE LYMPH NODES, NO TUMOR PRESENT (0/9).
- THIS INCLUDES EIGHT MEDIASTINAL LYMPH NODES (N10L, N11L X2, N6, N9L, N7), AND ONE PERIBRONCHIAL LYMPH NODE.

COMMENT: [REDACTED] has reviewed representative slides, and concurs with the diagnosis of invasive squamous cell carcinoma.

Lung Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, [REDACTED] and CAP protocol, [REDACTED]

[page 2 of 5]
Procedure:	Lobectomy.
Specimen type:	Lobectomy.
Specimen laterality:	Left.
Specimen integrity:	Wedge excision (specimen A) containing tumor, followed by lobectomy specimen (specimen B).

TUMOR FEATURES:

Tumor site:	Left upper lobe of lung.
Tumor size:	1.9 cm.
Tumor focality:	Single focus.
Histologic type:	Squamous carcinoma.
Histologic grade:	Moderately differentiated.
Lymphovascular invasion:	Indeterminate.
Visceral pleural invasion:	Not identified.
Tumor extension into extrapulmonary structures:	Not identified.
Treatment effect:	Not applicable.

LYMPH NODES:

Eight mediastinal lymph nodes and one peribronchial lymph node, with no evidence of metastatic carcinoma.

MARGIN EVALUATION:

Distance to closest margin:	At least 5 cm from nearest margin (bronchial margin).
Bronchial margin:	Negative.
Vascular margin:	Negative.
Parenchymal margin:	Negative.
Parietal pleural margin:	Not applicable.
Chest wall margin:	Not applicable.

PATHOLOGIC TUMOR STAGING:

Primary tumor:	pT1a.
Regional lymph nodes:	pN0.
Distant metastasis:	Not applicable.
Margin status:	Negative.
Pathologic stage:	IA.

Additional pathologic findings:	Emphysematous changes.
---------------------------------	------------------------

[page 3 of 5]
FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Lung; Left lung Wedge resection LUL
- B. Lung; LUL
- C. Lymph node; N10L
- D. Lymph node; N11L
- E. Lymph node; N11L #2
- F. Lymph node; N6
- G. Lymph node; N9L
- H. Lymph node; N7

Clinical History/Operative Dx:

Left lung nodule.

Intraoperative Diagnosis:

- A. Left upper lobe wedge: Non-small cell carcinoma, favor squamous.
- B. Left upper lobe lung: Bronchial margin free of tumor. [REDACTED] The intraoperative interpretation(s) was/were performed and rendered at [REDACTED]

Gross Description:

A. The specimen is labeled wedge excision left upper lobe and is received without fixative. It consists of a wedge resection of lung measuring 6.6 x 2 x 2.4 cm and having a partially fixed weight of 11 grams. A T-shaped metallic staple line is present along one edge of the specimen. The pleural surface is pink-tan with anthracotic stippling. There is a palpable area of firmness in the central lung wedge. On sectioning, this palpable firmness is a discrete tan neoplasm which measures 1.9 x 1.9 x 1.4 cm. Centrally, it appears slightly fibrotic. A representative section of the neoplasm is submitted for frozen section as FSA1. The staple line is dissected free and the resection edge is inked. On further sectioning, the neoplasm is 0.4 cm from the closest staple line. The remainder of the lung wedge is composed of red soft pulmonary parenchyma. Representative sections are submitted.

Section summary: A1) representative section of neoplasm from frozen section, A2-A3) additional sections of neoplasm and stapled resection line, A4) uninvolved lung. [REDACTED]

B. The specimen is labeled left lung upper lobe and is received without fixative. It consists of a lobe of lung which measures 21 cm from superior to inferior, 11.5 cm from anterior to posterior, and 3 cm from medial to lateral. The pleural surface varies from tan to pink and there is extensive anthracotic stippling. There is a Y-shaped metallic staple line present along the posterior apical surface of the lung which is 8 cm in length. A second metallic staple line extends across the medial surface of the lung and posterior to the hilum, extending to the basilar edge. At the hilum, the bronchial margin is identified and removed as a thin shave for frozen section as FSB1. There is a single 0.9 cm anthracotic peribronchial node. Dissection of the bronchi reveals no intrabronchial tumor. The metallic staple line at the posterior apical portion of the lung is 5 cm from the hilum. Serial sections of the lung reveal no discrete masses. Representative sections are submitted.

[page 4 of 5]
FINAL SURGICAL PATHOLOGY REPORT

Section summary: B1) bronchial margin from frozen section, B2) vascular margins at hilum, B3) single peribronchial node, B4) sections of lung along posterior apical staple line, B5) additional apical lung sections, B6) additional sections of apical lung, B7) sections of mid lung, B8) sections of basilar lung.

C. The specimen is labeled lymph node and is received in formalin. It consists of a 1 x 0.7 x 0.4 cm anthracotic appearing lymph node. It is serially sectioned and submitted in cassette C1.

D. The specimen is labeled lymph node and is received in formalin. It consists of a 1.6 x 0.9 x 0.5 cm dull red to anthracotic node. It is serially sectioned and entirely submitted in cassette D1.

E. The specimen is labeled lymph node and is received in formalin. It consists of a 1.2 cm aggregate of anthracotic appearing tissue fragments which are submitted in cassette E1.

F. The specimen is labeled lymph node and is received in formalin. It consists of a 2.8 x 1.5 x 0.9 cm fragment of fibrofatty and anthracotic tissue. On dissection, it contains a 2.7 x 1.3 x 0.5 cm fragment of anthracotic and fibrofatty tissue. Within the fatty tissue are three smaller fragments of anthracotic tissue which vary from 0.2-0.3 cm in maximum dimension. The larger node is serially sectioned and submitted in cassettes F1 and F2. The smaller fragments are submitted in cassette F3.

G. The specimen is labeled and is received in formalin. It consists of a 1 x 0.5 x 0.2 cm fragment of fatty tissue which contains a discrete 0.4 cm area of anthracotic discoloration. The specimen is submitted intact in cassette G2.

H. The specimen is labeled 7 and is received in formalin. It consists of three fragments of predominantly anthracotic tissue which vary from 1.2 x 0.7 x 0.3 cm to 0.5 cm in maximum dimension. The two largest fragments are inked with contrasting colors. They are serially sectioned and combined with the remaining tissue in cassette H1.

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

D. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

E. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

F. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis

[page 5 of 5]
FINAL SURGICAL PATHOLOGY REPORT

rendered.

G. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

H. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Source: NCI Genomic Data Commons file fc9a7a13-e1c4-4dfb-bfe9-7e7710240a5f (TCGA-56-8626.7A75CBD1-A056-4677-A63B-43AAB3BB1379.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).